CPTAC case C3L-02627 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f8f3df64-54c1-4d1a-8ea7-c371b01c2ef6

Demographics
Sex at birth: female; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 64.8 years (23,667 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,820 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,820 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 497 days (1.4 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 823 days (2.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,051 days (2.9 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,051 days (2.9 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,411 days (3.9 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,820 days (5.0 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 70 kg; Height: 160 cm; BMI: 27.34; FEV1/FVC before bronchodilator (%): 94.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 45; Cigarettes per day: 30; Tobacco smoking onset year: 1987; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 35.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02627-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 1,094 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02627-24: Section location: Right Lower Lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-02627-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 233 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02627-25: Section location: Right Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3L-02627-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 1,243 mg; Time between clamping and freezing: 30 minutes; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02627-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
